Surgical pathology report (de-identified scan), TCGA case TCGA-OR-A5JY, project TCGA-ACC (Adrenocortical Carcinoma), tissue source site University of Michigan, specimen TCGA-OR-A5JY-01A (Primary Tumor).

[page 1 of 4]
OPER DATE:

PROCEDURE: APMI

ADDENDUM TO REPORT CHANGE IN MARGIN STATUS AFTER DISCUSSION WITH SURGEON:

=====

Please see revised template and revised diagnosis below.

ADRENOCORTICAL CARCINOMA
V4

Tumor Size: 17.1 x 12.5 x 10.3 cm.

Tumor Weight: Cannot determine.

Capsular Invasion: Yes.

Vascular Invasion: Yes.

Surgical Margins: Negative.

Necrosis: 75% (gross).

Mitotic Rate: 60/50 hps.

Grade: High.

Lymph nodes status: 1/2.

Extra-adrenal extension: Present.

Stage: 4 (pT3 N1 M1).

Immunohistochemistry Results: N.A.

ICD-6-B

Carcinoma, adrenal cortical
8370/3

Site: Adrenal Gland, cortex
C74.2

9201/301/3

PROCEDURE: APDX

2. Right adrenal and kidney, resection: High-grade adrenocortical carcinoma (17.1 cm) with capsular and extensive vascular invasion, including invasion of vasa cava. Margins negative. Please see TEMPLATE for details. Metastatic carcinoma in one of two lymph nodes (1/2). Incidental renomedullary interstitial cell tumor.

1 and 3. Please see previous report for diagnoses which remain unchanged.

the signing staff pathologist, have personally
examined and interpreted the slides from this case.

[page 2 of 4]
PREVIOUS DIAGNOSIS INQUIRY

REPORT DATE: [REDACTED]

BIRTHDATE: [REDACTED]

PAT TYPE: [REDACTED]

PAGE #: 3
SEX: F
ADM DATE: [REDACTED]

OPER DATE: [REDACTED]

OPER DATE: [REDACTED]

PROCEDURE: SPHS

History of anemia and right upper quadrant pain.

PROCEDURE: SPGD

1. "Right liver surface nodule, rule out metastatic cancer." Received fresh for frozen section is a 0.5 x 0.5 x 0.3 cm, tan nodule.
1A. Frozen section control.

2. "Right adrenal gland and kidney." Received in formalin in a large container is a radical nephrectomy specimen (1585 gm), consisting of: kidney (11.7 x 7.5 x 6.2 cm), adrenal tumor (17.1 x 12.5 x 10.3 cm), vena cava (1.5 x 1.8 cm), renal vein (3.2 x 2.6 cm), renal artery (3.9 x 0.5 cm), ureter (5.7 x 0.4 cm) and attached perirenal/periadrenal adipose. The vena cava is remarkable for an exophytic tumor thrombus, which extends 5.7 cm past the margin of resection. The adrenal tumor is inked blue and sectioned to reveal yellow-brown, variegated and friable cut surfaces remarkable for extensive areas of hemorrhage and necrosis (75%). The adrenal tumor is encapsulated within a thin, intact membrane. No normal adrenal parenchyma is identified. The adrenal tumor abuts the superior pole of the kidney, however, no involvement is identified. Found within the renal medulla of the mid pole is a 0.4 x 0.3 x 0.3 cm, gray, well-circumscribed nodule. The remaining renal parenchyma is unremarkable. The perirenal/periadrenal adipose, renal vein, renal artery and ureter are uninvolved and unremarkable. There are multiple possible lymph nodes up to 2.1 cm in greatest dimension. This case has been consulted with

- 2A. Vena cava margin including tumor thrombus.
- 2B. Renal vein, renal artery and ureter margins.
- 2C. Two possible lymph nodes submitted whole.
- 2D. One possible lymph node, serially sectioned.
- 2E. One possible lymph node, serially sectioned.
- 2F-I. Adrenal tumor including capsule.
- 2J-K. Center of adrenal tumor.
- 2L. Adrenal tumor to kidney.
- 2M. Renal nodule.

[page 3 of 4]
PREVIOUS DIAGNOSIS INQUIRY

REPORT DATE: _____

PAGE #: 4

BIRTHDATE: _____

PAT TYPE: _____

SEX: F

ADM DATE: _____

OPER DATE: _____

3. "Costochondral cartilage." Received in formalin in a small container is a 2.7 x 1.8 x 0.9 cm soft tissue and bone excision, including two embedded ribs, 1.7 cm segments each, and surrounded by grossly unremarkable skeletal muscle and fibrous tissue. No lesions are present. Specimen submitted for gross examination only.

FROZEN SECTION REPORT

1. Positive for metastatic carcinoma.

_____ have reviewed and interpreted the frozen section material at the time it was requested.

PROCEDURE: SPMI

ADRENOCORTICAL CARCINOMA
V4

Tumor Size: 17.1 x 12.5 x 10.3 cm.

Tumor Weight: Cannot determine.

Capsular Invasion: Yes.

Vascular Invasion: Yes.

Surgical Margins: Positive (vena cava and soft tissue).

Necrosis: 75% (gross).

Mitotic Rate: 60/50hpf.

Grade: High.

Lymph nodes status: 1/2.

Extra-adrenal extension: Present.

Stage: 4 (pT3 N1 M1)

Immunohistochemistry Results: N/A

[page 4 of 4]
REPORT DATE: 1-1-68

PAT TYPE:

OPER DATE:

1. Liver, right surface nodule, biopsy: Metastatic carcinoma.
2. Right adrenal and kidney, resection: High-grade adrenocortical carcinoma (17.1 cm) with capsular and extensive vascular invasion, including invasion of the vena cava. Carcinoma present at vena cava margin and focally at soft tissue margin. See TEMPLATE. Metastatic carcinoma in one of two lymph nodes (1/2). Incidental renomedullary interstitial cell tumor.
3. Bone and soft tissue, "costochondral cartilage", resection: Unremarkable bone and soft tissue. Gross only.

the signing pathologist, have personally examined and interpreted the slides from this case.

** END OF PREVIOUS DIAGNOSIS INQUIRY **

Dual/multichronous Primary Noted		

Source: NCI Genomic Data Commons file 812969bd-f0d0-4459-9642-c5fe286a28c3 (TCGA-OR-A5JY.8D4E0E4D-9C84-4F29-AFD9-91EEEC158ED6.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).